MMRF case MMRF_1721 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e8280528-4fd6-44fc-b15b-72c78e4161bf

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.5 years (21,017 days); ISS stage: I; Days to last known disease status: 120 days; Days to last follow up: 120 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 120 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -36 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 62.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.156 mg/dL; Immunoglobulin G 4.63 g/L; Immunoglobulin A 46.1 g/L; Immunoglobulin M 0.92 g/L; Beta 2 Microglobulin 2.79 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 11.1 g/dL; Glucose 5.56 mmol/L.
- Day 57: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Hemoglobin 8.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.5 mmol/L.
- Day 120 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.138 mg/dL; Hemoglobin 8.62 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -36: Weight: 74 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1721_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -36 days.
- Sample MMRF_1721_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -36 days.
